Gene-level copy-number profile of tumor specimen C3N-02327-01 from CPTAC case C3N-02327, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 45.5 years (16,633 days).
Specimen C3N-02327-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1fdd1fac-96e8-4a43-8e7c-047248d452e2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02327-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,252 have no estimate.
https://portal.gdc.cancer.gov/files/6a4b8557-022c-43c1-b7cf-7e09a4105513

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 27; copy number 1: 7,335; copy number 2: 43,608; copy number 3: 7,382; copy number 4: 19.

Homozygous deletions (total copy number 0; autosomes only): 27 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:16,199,203–16,333,978, 4 genes (within-gene range 0–1): AC142283.1, AC010745.1, AC010745.2, AC010745.3.
- chr9:21,966,929–21,967,751, 1 gene (within-gene range 0–1): CDKN2A-DT.
- chr9:65,189,995–65,250,826, 4 genes: BMS1P12, AL512605.1, AL512605.2, IGKV1OR9-1.
- chr22:18,422,244–18,757,906, 17 genes: FAM230A, AC023490.2, FAM247B, GGTLC3, Metazoa_SRP, AC023490.3, TMEM191B, PI4KAP1, AC023490.1, RN7SKP131, RIMBP3, Metazoa_SRP, SUSD2P2, CA15P2, PPP1R26P2, PPP1R26P4, FAM230E.
- chr22:18,794,414–18,794,804, 1 gene (within-gene range 0–1): AC008132.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 7,335. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
